Gene-level copy-number profile of tumor specimen TCGA-66-2763-01A from TCGA case TCGA-66-2763, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 63.8 years (23,315 days).
Specimen TCGA-66-2763-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.d5a748bf-42eb-4797-93a4-c045893dfd4c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-66-2763-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3beb2962-155e-4ce4-ab97-e85623feb841

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 1,362; copy number 2: 20,372; copy number 3: 11,360; copy number 4: 16,669; copy number 5: 5,247; copy number 6: 3,235; copy number 7: 813; copy number 8: 211; copy number 9: 268; copy number 10: 64; copy number 11: 26; copy number 13: 112; copy number 16: 28; copy number 26: 7; copy number 27: 26; copy number 40: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-66-2763-01A-01D-0844-01): tumor purity 0.67, ploidy 1.71, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:12,897,043–13,283,281, 2 genes (within-gene range 0–2): IQSEC1, AC069271.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9,652 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:123,762,171–124,989,325, 10 genes, copy number 6–9: PSMD14P1, AC064859.1, RN7SKP102, AC079154.1, CNTNAP5, MTND5P22, AC019159.2, AC019159.1, RNA5SP102, RNU6-259P.
- chr3:68,004,247–68,637,024, 6 genes, copy number 7 (within-gene range 2–7): TAFA1, COPS8P2, AC107626.1, AC104167.1, AC096922.1, PSMC1P1.
- chr3:93,843,764–198,222,513, 1,800 genes, copy number 5–6 (broad region; genes not listed).
- chr4:54,603,211–55,636,698, 27 genes, copy number 10–26: LINC02260, KIT, AC097494.1, LINC02358, AC111194.1, RPL38P3, RNU6-410P, AC111194.2, RN7SL424P, KDR, AC021220.2, RN7SL822P, AC021220.1, RNU6-746P, LRRC34P2, SRD5A3, FCF1P8, SRD5A3-AS1, AC069200.1, TMEM165, Y_RNA, CLOCK, Y_RNA, RN7SKP30, AC024243.1, PDCL2, NMU.
- chr5:58,198–3,181,487, 87 genes, copy number 5 (broad region; genes not listed).
- chr6:75,237,675–77,927,028, 35 genes, copy number 5–6: COX7A2, TMEM30A, TMEM30A-DT, FILIP1, HMGB1P39, AL445465.1, U3, MIR4463, AL445465.2, UBE2V1P15, RNU1-34P, RPL26P20, H3P27, RNU6-1338P, SENP6, AL356057.1, RNU6-1016P, RN7SKP163, AL109897.1, MYO6, RNU6-155P, RNA5SP209, IMPG1, Y_RNA, RNU6-248P, RNU6-261P, LINC02540, RNU6-84P, AL591030.1, AL590426.1, AL355612.1, AL365222.1, HTR1B, RPS6P7, MEI4.
- chr8:34,228,439–145,066,685, 1,732 genes, copy number 5–40 (broad region; genes not listed).
- chr10:47,300,197–47,357,881, 3 genes, copy number 7: GDF10, GDF2, RBP3.
- chr11:55,325,756–135,075,908, 2,166 genes, copy number 5 (broad region; genes not listed).
- chr12:72,610,678–72,728,844, 2 genes, copy number 5: CHCHD3P2, AC133480.1.
- chr14:18,333,726–106,875,071, 2,285 genes, copy number 5–7 (broad region; genes not listed).
- chr16:15,395,754–35,118,956, 734 genes, copy number 6 (broad region; genes not listed).
- chr18:47,390–1,408,344, 43 genes, copy number 5: TUBB8B, AP001005.3, IL9RP4, AP001005.2, ROCK1P1, MIR8078, USP14, THOC1, AP000845.1, AP000915.1, COLEC12, AP000915.2, LINC01925, CETN1, RN7SKP146, CLUL1, AP001178.4, TYMSOS, AP001178.3, AP001178.1, TYMS, ENOSF1, AP001178.2, YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1, AP000894.1, AP000894.3, AP000894.2, ADCYAP1, LINC01904, AP005328.1, AP000829.1, SLC25A3P3, COX6CP3, LINC00470, RN7SKP72, AP005119.1, AP005119.2.
- chr20:3,043,622–6,780,246, 104 genes, copy number 6–10 (broad region; genes not listed).
- chr21:15,190,406–17,211,347, 27 genes, copy number 5–8 (within-gene range 2–8): AF222685.1, AF130248.1, AF246928.1, AJ009632.2, CYCSP42, AJ009632.1, RNU6-1326P, RAD23BP3, USP25, RBPMSLP, MIR99AHG, RNU6-426P, VDAC2P1, RPS26P5, SNORD74B, AP001172.1, AP001172.2, AP000962.3, AP000962.2, MIR99A, MIRLET7C, AP000962.1, MIR125B2, RNU1-98P, AF130359.1, AF212831.1, NEK4P1.
- chr22:27,978,014–28,679,865, 1 gene, copy number 5 (within-gene range 3–5): TTC28.
- chr22:28,056,153–45,977,162, 590 genes, copy number 5–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,362. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
